Somatic mutation profile of tumor specimen C3L-08265-03 (aliquot CPT0477690006) from CPTAC case C3L-08265, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.0 years (22,274 days).
Specimen C3L-08265-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b36cfe2-b664-4020-a718-79325dc3d5e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08265-31 (Blood Derived Normal), aliquot CPT0475690003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0726a6a4-4422-42c7-94a3-6ca9a5372a65

The open-access MAF lists 78 somatic variants for this specimen: 52 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 23, Intron 2, Splice Site 2, Nonsense Mutation 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 28/392 reads (7%) | catalogued as rs778376925, CD064644, CM981863, CM991149, COSV58820509, COSV58821737, COSV58821906; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 58/248 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C10orf71 | c.3847G>A p.G1283R | Missense Mutation (SNP) | VAF 52/507 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047765296, COSV60504292, COSV60514472; called by muse, mutect2, varscan2
- C1orf94 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1214589775, COSV64915708; called by muse, mutect2
- CEBPZ | c.3056G>A p.R1019H | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs948144685; called by muse, mutect2, varscan2
- CHD8 | c.2764G>A p.A922T (on ENST00000646647 / NM_001170629.2; = p.A643T on NM_020920.4) | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1013103711, COSV101303007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTDNEP1 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.005); catalogued as rs1212337419; called by muse, mutect2, varscan2
- CTDSP2 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs745742336; called by muse, mutect2, varscan2
- CYBB | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 112/521 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146275471; called by muse, mutect2, varscan2
- EYA1 | c.1403G>A p.R468K | Missense Mutation (SNP) | VAF 20/459 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs755093166; called by muse, mutect2
- FAM118A | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs141212109; called by muse, mutect2, varscan2
- FMN2 | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 64/586 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV60429708; called by muse, mutect2
- FTHL17 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 131/576 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.485); catalogued as rs1348661585, COSV63267923, COSV63268194; called by muse, varscan2
- HUWE1 | c.2440G>C p.D814H | Missense Mutation (SNP) | VAF 99/487 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53337961, COSV53345647; called by muse, mutect2, varscan2
- KIAA1614 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 102/562 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377550267; called by muse, mutect2, varscan2
- OR13C4 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs757616110, COSV52927457, COSV52928115; called by muse, mutect2
- PIWIL1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.719); catalogued as rs1044176882, COSV55346127; called by muse, mutect2, varscan2
- PLEKHA6 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 44/441 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs200071766, COSV55338877; called by muse, mutect2
- SNX20 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 47/484 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as rs778094287; called by muse, mutect2
- SPN | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64070005; called by muse, mutect2, varscan2
- TAS2R42 | c.745dup p.S249Ffs*55 | Frame Shift Ins (INS) | VAF 49/354 reads (14%) | catalogued as rs753101364; called by mutect2, varscan2
- TBX15 | c.1795G>A p.V599M (on ENST00000369429 / NM_001330677.2; = p.V493M on NM_152380.3) | Missense Mutation (SNP) | VAF 57/280 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.031); catalogued as rs922050997; called by muse, mutect2, varscan2
- TECTA | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 102/411 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs370652301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.95203G>C p.D31735H (on ENST00000591111; = p.D24311H on NM_003319.4) | Missense Mutation (SNP) | VAF 38/337 reads (11%) | PolyPhen benign (0.255); catalogued as COSV59880556; called by muse, mutect2, varscan2
- WAS | c.1348G>T p.A450S | Missense Mutation (SNP) | VAF 110/456 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as CD130991; called by muse, mutect2, varscan2
- WFDC8 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 44/650 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.514); catalogued as rs377581195, COSV51489818; called by muse, mutect2
- ZBTB42 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 97/395 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs753486490; called by muse, mutect2, varscan2
- ZNF616 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 65/705 reads (9%) | catalogued as rs765345694, COSV57512656; called by muse, mutect2
- ZNF780A | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 85/498 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as rs751047796, COSV61815736; called by muse, mutect2, varscan2
- AK9 | c.1588G>C p.A530P | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- CBLN4 | c.291+1G>A p.X97_splice | Splice Site (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- CDH22 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 34/563 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2
- DMD | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNM1 | c.996G>T p.M332I | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ELAPOR2 | c.2477C>G p.S826C (on ENST00000450689 / NM_001142749.3; = p.S659C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAM124B | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- FAM207A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- FOXC2 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- GPALPP1 | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRIN2B | c.2234G>C p.G745A | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- L3MBTL4 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC16 | c.41420A>C p.N13807T | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); called by mutect2, varscan2
- PGA3 | c.919-1G>C p.X307_splice | Splice Site (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- PGBD5 | c.509T>A p.L170Q (on ENST00000525115; = p.L239Q on NM_001258311.2) | Missense Mutation (SNP) | VAF 47/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1 | c.7895T>A p.I2632N | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.075); called by muse, mutect2
- PTPRT | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF187 | c.287T>A p.L96Q | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SEPSECS | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGCD | c.11A>G p.E4G (on ENST00000435422 / NM_001128209.2; = p.E5G on NM_000337.5) | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- TEX15 | c.627T>G p.I209M (on ENST00000256246; = p.I592M on NM_001350162.2) | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TUT7 | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, varscan2
- ZNF804B | c.3272C>A p.T1091N | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ALKBH5 | c.309C>T p.I103= | Silent (SNP) | VAF 80/400 reads (20%) | called by muse, mutect2, varscan2
- BCR | c.3543C>T p.F1181= | Silent (SNP) | VAF 33/296 reads (11%) | catalogued as COSV59932955; called by muse, mutect2, varscan2
- CENPK | c.261C>T p.D87= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs765236390; called by muse, mutect2, varscan2
- CINP | c.207C>T p.S69= | Silent (SNP) | VAF 37/255 reads (15%) | called by muse, mutect2, varscan2
- CPXM1 | c.2160G>A p.P720= | Silent (SNP) | VAF 50/329 reads (15%) | catalogued as rs780367464, COSV66045128; called by muse, mutect2, varscan2
- CRACDL | c.2469G>A p.A823= | Silent (SNP) | VAF 43/383 reads (11%) | catalogued as rs765707391, COSV67407176; called by muse, mutect2, varscan2
- CTNNAL1 | c.2169A>G p.S723= | Silent (SNP) | VAF 36/282 reads (13%) | called by muse, mutect2, varscan2
- DGKD | c.1041C>T p.N347= (on ENST00000264057 / NM_152879.3; = p.N303= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/356 reads (5%) | called by muse, mutect2
- FOXG1 | c.51G>A p.S17= | Silent (SNP) | VAF 33/258 reads (13%) | called by muse, varscan2
- GABRA1 | c.438G>T p.L146= | Silent (SNP) | VAF 35/361 reads (10%) | catalogued as rs1415205830; called by muse, mutect2, varscan2
- MAML3 | c.885G>A p.Q295= | Silent (SNP) | VAF 25/424 reads (6%) | catalogued as rs756516423, COSV59072648; called by muse, mutect2
- MEX3A | c.978C>T p.P326= | Silent (SNP) | VAF 105/475 reads (22%) | catalogued as rs561442043, COSV68479086; called by muse, mutect2, varscan2
- MYBPC3 | c.1071C>T p.R357= | Silent (SNP) | VAF 46/302 reads (15%) | catalogued as rs371308153; called by muse, mutect2, varscan2
- PRRX1 | c.48C>A p.G16= | Silent (SNP) | VAF 70/366 reads (19%) | catalogued as COSV53412787; called by muse, mutect2, varscan2
- RRP12 | c.1500G>A p.A500= | Silent (SNP) | VAF 40/343 reads (12%) | catalogued as rs537742721; called by muse, mutect2, varscan2
- RTN4 | c.1080G>A p.V360= | Silent (SNP) | VAF 54/300 reads (18%) | called by muse, mutect2, varscan2
- SALL3 | c.1911C>T p.P637= | Silent (SNP) | VAF 71/597 reads (12%) | catalogued as rs1283148710, COSV101609962; called by muse, mutect2, varscan2
- SLC37A2 | c.840C>T p.C280= | Silent (SNP) | VAF 91/506 reads (18%) | catalogued as rs751379723; called by muse, mutect2, varscan2
- STOX2 | c.804A>G p.L268= | Silent (SNP) | VAF 51/322 reads (16%) | called by muse, mutect2, varscan2
- TMEM132C | c.237G>C p.A79= | Silent (SNP) | VAF 58/407 reads (14%) | called by muse, mutect2, varscan2
- TSHZ3 | c.1899G>T p.G633= | Silent (SNP) | VAF 16/512 reads (3%) | called by muse, mutect2
- TTC28 | c.5589G>T p.V1863= | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- TTN | c.6558G>A p.K2186= (on ENST00000591111; = p.K2140= on NM_003319.4) | Silent (SNP) | VAF 18/382 reads (5%) | catalogued as rs1255684366; called by muse, mutect2
- BRD2 | c.-1222G>A | 5'UTR (SNP) | VAF 55/410 reads (13%) | called by muse, mutect2, varscan2
- CSF2RA | c.1125+109G>A | Intron (SNP) | VAF 68/391 reads (17%) | catalogued as rs756499032, COSV100817510, COSV62625556; called by muse, mutect2, varscan2
- USH1C | c.1285-7680C>G | Intron (SNP) | VAF 24/386 reads (6%) | called by muse, mutect2
